Surgical pathology report (de-identified scan), TCGA case TCGA-29-1783, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1783-01A (Primary Tumor).

[page 1 of 2]
BLOCK SUMMARY:

TCGA-29-1783

- E1- surgical margin closest to tumor
- E2- opposite surgical margin
- E3- tumor with overlying mucosa
- E4- tumor with overlying mucosa
- E5- additional representative sections of tumor
- E6- uninvolved colonic mucosa

F. "Surface nodule liver", received is a 1.2 x 1 x 0.1 cm fragment of soft tan tissue which is submitted entirely in block F1.

G. "Omentum (additional specimen)", received is a 10.5 x 9 x 0.8 cm fragment of fibroadipose tissue which contains several (greater than 10) nodules. The largest nodule (2 x 1.5 x 0.8 cm is upon sectioning white-tan and with no necrosis or hemorrhage.

BLOCK SUMMARY:

G1-2- representative sections of nodule

H. "Donut rings", received is a 3.5 x 3 x 1 cm aggregate of colonic mucosa and underlying smooth muscle the mucosal surface is present normal folding pattern, there are no perforations for lesions. Representative sections are submitted in block H1.

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1 (representative)- carcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Exploratory laparotomy, right salpingo-oophorectomy, omentectomy, partial colectomy.

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "OMENTUM" (OMENTECTOMY):

METASTATIC SEROUS ADENOCARCINOMA.
TUMOR SIZE: GREATER THAN 2 CM.

B. "OMENTUM" (OMENTECTOMY):

METASTATIC SEROUS ADENOCARCINOMA.
TUMOR SIZE: GREATER THAN 2 CM.

C. "RIGHT OVARY AND TUBE" (SALPINGO-OOPHORECTOMY):

[page 2 of 2]
TCGA-29-1783

SEROUS PAPILLARY ADENOCARCINOMA OF THE OVARY
FIGO GRADE: 3 OF 3.
TUMOR SIZE: 3.5 X 2 X 1.9 CM.
SEROVA: POSITIVE FOR CARCINOMA.

D. "RIGHT DIAPHRAGM" (BIOPSY):

METASTATIC SEROUS ADENOCARCINOMA.

E. "RECTOSIGMOID" (PARTIAL COLECTOMY):

SEGMENT OF COLON WITH METASTATIC SEROUS ADENOCARCINOMA.

F. "LIVER, SURFACE NODULE" (BIOPSY):

METASTATIC SEROUS ADENOCARCINOMA.

G. "OMENTUM, ADDITIONAL SPECIMEN" (OMENTECTOMY):

METASTATIC SEROUS ADENOCARCINOMA.

H. "DONUT RINGS" (PARTIAL COLECTOMY):

FRAGMENTS OF COLON WITH MICROSCOPIC FOCI OF METASTATIC SEROUS
ADENOCARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 345f0ec8-f0ab-4ab0-ad61-20fce4733c63 (TCGA-29-1783.6EBF4763-BB2A-4EF5-AB22-23460980DF1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).